CPTAC case C3L-06074 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f7229f5e-a898-45fc-8423-b264edeb37d8

Demographics
Sex at birth: male; Race: white; Year of birth: 1988; Vital status: Dead; Days to death: 1,431 days (3.9 years); Year of death: 2023; Cause of death: Cancer Related; Country of birth: Turkey.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 30.9 years (11,274 days); Year of diagnosis: 2019; Days to last known disease status: 1,431 days (3.9 years); Days to last follow up: 1,431 days (3.9 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (4 entries)
- Days to follow up: 664 days (1.8 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,244 days (3.4 years); Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,431 days (3.9 years); Karnofsky performance status: 0; ECOG performance status: 5.
- Follow-up contact recording only the day: day 370.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-06074-50, C3L-06074-51, C3L-06074-52 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-06074-54, C3L-06074-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
